Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2R8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2R8-01A (Primary Tumor).

[page 1 of 5]
Surgical Final Report | Temporary Copy

Page 1 of 5

Case:
Collected:
Ordered by:

Patient:
ID:
Location:

MS Specimen

A) Uterus, cervix, bilateral ovaries/fallopian tube, upper 1/3 vagina. B) Right pelvic lymph nodes. C) Left pelvic lymph nodes.

MS Clinical History

Invasive cervical cancer.

ICB-0-3
carcinoma, squamous cell, Nos 8070/3
Site: cervix, Nos C53.9 lw 9/8/11

MS Gross Description

The specimens are received fresh in three containers, each designated with the patient's name

Part A is designated "uterus, cervix, BSO". The specimen consists of a total hysterectomy specimen to include a uterus with attached cervix and attached bilateral adnexa. The left fallopian tube with fimbriae that is moderately hemorrhagic is 2 cm in length and up to 0.7 cm in diameter. The ovary is tan-pink and 2 cm in greatest dimension. Bivalving reveals a normal ovarian architecture as well as a 0.6 cm in greatest dimension cystic structure containing a serosanguineous fluid. The right fallopian tube is also hemorrhagic, 4 cm in length and up to 0.6 cm in diameter. The ovary is tan, gray-purple, 3.5 cm in greatest dimension. Sectioning reveals a normal ovarian architecture as well as a few cystic structures containing a serous to serosanguineous fluid ranging from 1.5 to 1.0 cm. There is also a paratubal cyst containing a clear fluid and smooth inner lining, 0.6 cm in greatest dimension.

The uterus cervix is 247 g, 13 x 8.5 x 5.9 cm. The serosa is tan-pink and predominantly smooth. The paracervical/parametrial margin is inked black. The attached cervical cuff is 2 cm in depth approximately 12 o'clock and 2.5 at the 6 o'clock aspect. There is a large cervical mass on the anterior cervix protruding through the os. Upon bivalving, the endocervical canal is 2.5 cm and the endometrial cavity is 3.5 cm from cornu to cornu. The distance from fundus to squamocolumnar junction is approximately 7.5 cm. This cervical mass described above is 5.5 x 5.5 x 3.7 cm, approximately 3.2 cm from the closest vaginal cuff resection margin (12 o'clock). It is also well away from the endometrial cavity. Sectioning through the cervical mass is approximately 2.5 cm in depth and well away from the paracervical, parametrial, and paravaginal margins (closest 2 cm, parametrial margin). The endometrium is 0.4 cm in thickness and the myometrium is 2.7 cm in thickness. The parenchyma is of normal uterine architecture. Sectioning the soft tissue on both the left and right parametrial side, the right side has a small 0.4 cm nodule and the left has a 1.2 cm in greatest dimension firm nodule. The specimen is submitted as per code of sections.

CODE OF SECTIONS:

- A1 Left fallopian tube and ovary
- A2 Right fallopian tube and ovary
- A3 Vaginal cuff margin 12 o'clock to 3 o'clock (red ink 12 o'clock), en face
- A4 Vaginal cuff margin 3 o'clock to 6 o'clock (red ink 3 o'clock), en face
- A5 Vaginal cuff margin 6 o'clock to 9 o'clock (red ink 6 o'clock), en face

[page 2 of 5]
Surgical Final Report Temporary Copy

Page 2 of 5

Case:

Collected:

Ordered by:

Patient:

ID:

Location:

A6	Vaginal cuff margin 9 o'clock to 12 o'clock (red ink 9 o'clock), en face
A7	Anterior endometrium/myometrium
A8	Posterior endometrium/myometrium
A9-A10,	
A11-A12	Cervical mass with relation to parametrial margin (black ink), bisected
A13-A15	Full thickness section of cervical mass, trisected
A16	Large nodule from parametrial soft tissue, left side
A17	Small parametrial soft tissue nodule, right side

Part B is designated "right pelvic lymph nodes". The specimen consists of lobulated adipose tissue, 6.5 x 6.0 x 3.0 cm in aggregate dimension. Sectioning reveals 8 lymph node candidates ranging from 0.2 to 1.2 cm. The specimen is submitted as per code of sections.

CODE OF SECTIONS:

B1	Four lymph nodes, intact
B2	Single lymph node, bisected
B3	Single lymph node, bisected
B4	Single lymph node, bisected
B5	Two lymph nodes, intact

Part C is designated "left pelvic lymph nodes". The specimen consists of lobulated adipose tissue, 5.2 x 4.2 x 2.2 cm in aggregate dimension. Sectioning reveals six lymph node candidates ranging from 0.2 to 0.8 cm. The specimen is submitted as per code of sections.

CODE OF SECTIONS:

C1	Single lymph node, bisected
C2	Single lymph node, bisected
C3	Single lymph node, trisected
C4	Single lymph node, trisected
C5	Two lymph nodes, intact

MS Microscopic Description

Sections of the left and right fallopian tubes and ovaries labeled A1 and A2 exhibit hemorrhagic corpus luteal cysts. Old corpora lutea are also seen. The accompanying fallopian tubes are unremarkable. The right ovary shows a follicular cyst. A paratubal cyst is also seen in the right fallopian tube.

Sections labeled A3 through A6 from the circumferential vaginal cuff margin show segments of normally maturing squamous mucosa. No evidence of malignancy is seen in the multiple sections examined.

Sections of the uterine body reveal a secretory endometrium. Areas of superficial adenomyosis are identified. No evidence of malignancy is seen in the sections examined.

[page 3 of 5]
Surgical Final Report ...
Temporary Copy

Page 3 of 5

Case:
Collected:
Ordered by:

Patient: [REDACTED]
ID:
Location:

Part A9 through A15 reveals multiple segments of cervix which show a large invasive poorly-differentiated squamous cell carcinoma. Tumor necrosis is seen in several areas. Focal apoptotic and keratinizing cells are seen at the base of the tumor. A glandular component is not appreciated. Many of the tumor cells exhibit a large amount of eosinophilic cytoplasm. Numerous atypical mitoses are seen. Koilocytic atypia is seen focally along the surface. Overall, the tumor has a pushing margin.

Part A16 from the left parametrial nodule reveals a lymph node which exhibits metastatic squamous cell carcinoma. No extranodal extension is seen.

Part A17 shows a small lymph node from the right parametrial region. This shows no evidence of malignancy.

Part B from the right pelvic lymph nodes show metastatic squamous cell carcinoma in 1 of 9 lymph nodes.

Part C from the left pelvic lymph nodes show 6 lymph nodes without evidence of malignancy.

MS Diagnosis

A. Uterus, radical hysterectomy with bilateral salpingo-oophorectomy:

Invasive poorly-differentiated squamous cell carcinoma of uterine cervix, grade III (see Comment).

Tumor Stage: **pT1b2 [FIGO IB2]; pN1; pMX.**

Margins uninvolved by invasive carcinoma (see Comment).

Secretory endometrium.

Superficial adenomyosis.

Ovaries, right and left:

Hemorrhagic corpus luteal cysts and follicular cyst.

Fallopian tubes, right and left:

No pathologic alterations.

Left parametrial lymph node:

Metastatic squamous cell carcinoma.

Right parametrial lymph node:

No evidence of malignancy.

B. Right pelvic lymph nodes:

Metastatic squamous cell carcinoma in 1 of 9 lymph nodes.

C. Left pelvic lymph nodes:

Six lymph nodes showing no evidence of malignancy.

MS Comment

[page 4 of 5]
**Surgical Final Report
Temporary Copy**

Page 4 of 5

Case:

Collected:

Ordered by:

A: Cervix, Macroscopic

SPECIMEN TYPE:

Radical Hysterectomy

TUMOR SITE:

Right superior quadrant

Left superior quadrant

TUMOR SIZE:

Greatest dimension: 5.5 cm

*Additional dimensions: 5.5 x 3.7 cm

OTHER ORGANS PRESENT:

Right ovary

Left ovary

Right fallopian tube

Left fallopian tube

Uterine corpus

Vagina

A: Cervix, Microscopic

HISTOLOGIC TYPE:

Squamous cell carcinoma

HISTOLOGIC GRADE:

G3: Poorly differentiated

PRIMARY TUMOR (pT) TNM [FIGO]:

pT1b2 [IB2]: Cervical carcinoma confined to uterus, clinically visible lesion more than 4.0 cm in greatest dimension

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 17

Number involved: 2

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of tumor from closest margin: 20 mm

Specify margin, if possible: Parametrial margin

*VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

*Absent

MS Transcribed:

[page 5 of 5]
Surgical Final Report |
Temporary Copy

Page 5 of 5

Case:
Collected: .
Ordered by. .

Patient:
ID:
Location:

Source: NCI Genomic Data Commons file c2e017db-4aa5-446a-9e24-83e9ccd82cf5 (TCGA-EK-A2R8.7E69142C-4F3A-4F81-9DC8-72C86F689083.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).